Gene-level copy-number profile of tumor specimen HCM-CSHL-0868-C56-06A from HCMI case HCM-CSHL-0868-C56, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous surface papillary carcinoma; Tissue or organ of origin: Ovary; AJCC pathologic stage: Stage IIIB; FIGO stage: Stage IIIB; Tumor grade: High Grade; Age at diagnosis: 62.3 years (22,759 days).
Specimen HCM-CSHL-0868-C56-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c92e5f48-acc4-4a61-8a51-e8d8eccc41ba.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0868-C56-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,247 have no estimate.
https://portal.gdc.cancer.gov/files/6f3a82e0-1307-40ff-bb57-7cebdb07fc3b

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 2; copy number 2: 24,222; copy number 3: 2,250; copy number 4: 25,793; copy number 5: 12; copy number 6: 6,055; copy number 7: 2; copy number 8: 36.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:109,940,104–110,135,565, 2 genes: ADD3-AS1, ADD3.
- chr21:8,603,547–8,680,934, 2 genes: RPSAP68, CR381572.2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 2. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
